Somatic mutation profile of tumor specimen TCGA-DM-A285-01A (aliquot TCGA-DM-A285-01A-11D-A16V-10) from TCGA case TCGA-DM-A285, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IV; Age at diagnosis: 71.2 years (26,021 days).
Specimen TCGA-DM-A285-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4d65c78-e86e-4559-aac1-e321b23147ec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DM-A285-10A (Blood Derived Normal), aliquot TCGA-DM-A285-10A-01D-A16V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cfbdcd21-17e6-4514-b7fe-bd9eb99cd5de

The open-access MAF lists 174 somatic variants for this specimen: 133 protein-altering or splice-affecting, 38 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 115, Silent 38, Nonsense Mutation 9, Frame Shift Del 5, Intron 2, Splice Site 2, Frame Shift Ins 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2621C>G p.S874* | Nonsense Mutation (SNP) | VAF 7/38 reads (18%) | catalogued as rs1554084318, COSV57325449, COSV99970659; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4222G>T p.E1408* | Nonsense Mutation (SNP) | VAF 22/57 reads (39%) | hotspot (GDC flag); catalogued as CM106374, COSV57326063, COSV57397024; called by muse, mutect2, varscan2
- KRAS | c.57G>C p.L19F | Missense Mutation (SNP) | VAF 19/104 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs121913538, CM155383, COSV55502103, COSV55521217; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 36/164 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by mutect2, varscan2
- SMAD4 | c.1054G>A p.G352R | Missense Mutation (SNP) | VAF 16/73 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912581, CM024126, COSV61684989, COSV61690191; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.993+1G>A p.X331_splice | Splice Site (SNP) | VAF 17/33 reads (52%) | hotspot (GDC flag); catalogued as rs11575997, CD002536, COSV52663229, COSV52699909, COSV52752826; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA13 | c.10709T>A p.F3570Y | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV71295421; called by muse, mutect2, varscan2
- ABCC4 | c.198A>T p.K66N | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV65318996; called by muse, mutect2, varscan2
- ADCY1 | c.2897A>G p.N966S | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV52043385; called by muse, mutect2, varscan2
- ALMS1 | c.821G>C p.S274T | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV52523226; called by muse, mutect2, varscan2
- ANKRD12 | c.5002G>A p.D1668N | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as COSV50853042; called by muse, mutect2, varscan2
- APPL2 | c.779C>G p.S260C | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.451); catalogued as rs772596522, COSV51594356; called by muse, mutect2, varscan2
- ASIC5 | c.526T>C p.Y176H | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV72233064; called by muse, mutect2, varscan2
- ASPM | c.6539T>A p.V2180E | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.379); catalogued as COSV54139821; called by muse, mutect2, varscan2
- BAHCC1 | c.5503C>T p.R1835W | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs782754701, COSV57025455; called by muse, mutect2, varscan2
- BCL9 | c.1873C>T p.Q625* | Nonsense Mutation (SNP) | VAF 12/41 reads (29%) | catalogued as COSV52350756; called by muse, mutect2, varscan2
- BFSP1 | c.895C>A p.Q299K | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.493); catalogued as COSV64902070; called by muse, mutect2
- CAMSAP1 | c.1691C>A p.P564H | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.343); catalogued as COSV56729046; called by muse, mutect2, varscan2
- CLDN16 | c.289C>A p.L97I | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.11); catalogued as COSV53229493; called by muse, mutect2, varscan2
- CLYBL | c.940T>A p.F314I | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59229816; called by muse, mutect2, varscan2
- CNDP1 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs200702092, COSV100722564; called by muse, mutect2, varscan2
- COG3 | c.1009G>T p.D337Y | Missense Mutation (SNP) | VAF 17/280 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.804); catalogued as rs1344731155, COSV100596771; called by muse, mutect2
- CTTNBP2 | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs752206807, COSV50488235; called by muse, mutect2, varscan2
- DHX8 | c.1547C>T p.A516V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as rs749540850, COSV99292177; called by mutect2, varscan2
- DOCK11 | c.625A>T p.K209* | Nonsense Mutation (SNP) | VAF 8/106 reads (8%) | catalogued as COSV99354909; called by muse, mutect2
- DOCK4 | c.3752G>A p.R1251H | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1410289140, COSV69855339; called by muse, mutect2, varscan2
- DOP1A | c.4843G>C p.E1615Q | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.986); catalogued as COSV52715264, COSV52719129; called by muse, mutect2, varscan2
- ELL | c.468G>A p.L156= | Splice Region (SNP) | VAF 4/20 reads (20%) | catalogued as COSV99443805; called by mutect2, varscan2
- ELMO1 | c.850C>T p.R284W | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as rs1232187839, COSV100166366; called by muse, mutect2, varscan2
- EPSTI1 | c.20T>C p.V7A | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.046); catalogued as COSV100553236; called by muse, mutect2, varscan2
- ERBB4 | c.2804A>C p.K935T | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV100728237, COSV61522510; called by muse, mutect2, varscan2
- ERICH3 | c.2200T>C p.Y734H | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.901); catalogued as COSV100446004; called by muse, mutect2, varscan2
- EVA1C | c.452A>G p.Y151C | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100291644; called by muse, mutect2, varscan2
- EXD3 | c.2305G>T p.V769L | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100574027; called by muse, mutect2, varscan2
- FAM199X | c.813C>G p.S271R | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.975); catalogued as COSV55434535; called by muse, mutect2, varscan2
- FGD3 | c.1835G>A p.R612Q | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751133772, COSV61600270; called by muse, mutect2, varscan2
- FLRT1 | c.1883G>A p.R628H | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs761170027, COSV55361360; called by muse, mutect2, varscan2
- FNIP1 | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764541101, COSV57195010; called by muse, mutect2, varscan2
- GAS6 | c.1947C>G p.N649K | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as COSV59856317; called by muse, mutect2, varscan2
- GATAD1 | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as COSV55320427; called by muse, mutect2, varscan2
- GLB1L2 | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as rs202239114, COSV60278512; called by muse, varscan2
- GP2 | c.1538G>T p.G513V (on ENST00000381362 / NM_001007240.3; = p.G510V on NM_001502.4) | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV56895713, COSV56897004; called by muse, mutect2, varscan2
- GRIK4 | c.1414G>A p.V472M | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.781); catalogued as rs369283106; called by mutect2, varscan2
- GSK3B | c.468T>G p.I156M | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.14); catalogued as COSV51783859; called by muse, mutect2, varscan2
- GUF1 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs767862235, COSV55782156; called by muse, mutect2, varscan2
- HECW1 | c.4627G>A p.E1543K | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs370997480, COSV67831046; called by mutect2, varscan2
- HEPHL1 | c.2487C>G p.N829K | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100244496; called by muse, mutect2, varscan2
- HERC2 | c.8416G>A p.E2806K | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.71); PolyPhen benign (0.129); catalogued as rs763730325; called by muse, mutect2
- HFM1 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV54038324; called by muse, mutect2, varscan2
- HNRNPK | c.516+1G>T p.X172_splice | Splice Site (SNP) | VAF 45/109 reads (41%) | catalogued as COSV100699170; called by muse, mutect2, varscan2
- IFT122 | c.2302G>C p.V768L (on ENST00000348417 / NM_052989.3; = p.V709L on NM_018262.4) | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as COSV56202308, COSV56205725, COSV56208976; called by mutect2, varscan2
- IGSF1 | c.2812G>A p.G938R | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63840739; called by muse, mutect2, varscan2
- IGSF9B | c.3583G>T p.V1195L | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); catalogued as COSV58073496; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1660C>T p.R554C | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV56305151; called by muse, mutect2, varscan2
- ITGB2 | c.1565G>A p.R522Q (on ENST00000302347; = p.R498Q on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.138); catalogued as rs369318947; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ITPRID1 | c.668G>T p.S223I | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as COSV60083963; called by muse, mutect2, varscan2
- KLHL9 | c.231C>G p.F77L | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV100757183, COSV62922476; called by muse, mutect2, varscan2
- KMT2D | c.14864C>T p.S4955F | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as COSV56431885, COSV56491876; called by muse, mutect2, varscan2
- LCT | c.3748C>A p.P1250T | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV51558418; called by muse, mutect2, varscan2
- LMBRD2 | c.1685T>C p.M562T | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV99683314; called by muse, mutect2
- LRP2 | c.9592G>A p.E3198K | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.06); catalogued as rs189273089, COSV55544981; called by muse, mutect2, varscan2
- LUM | c.250A>G p.K84E | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as COSV99899218; called by muse, mutect2
- MASP2 | c.1127G>A p.R376Q | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs1051250399, COSV68897682; called by muse, mutect2, varscan2
- MEOX1 | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs375505737; called by muse, mutect2, varscan2
- MLH3 | c.3923T>C p.F1308S (on ENST00000355774 / NM_001040108.2; = p.F1284S on NM_014381.3) | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99470761; called by muse, mutect2, varscan2
- MTFR1L | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs200531392; called by muse, mutect2, varscan2
- MUC16 | c.32333C>T p.S10778L | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.011); catalogued as rs746103851, COSV67457535; called by muse, mutect2, varscan2
- MUC17 | c.13133G>C p.S4378T | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.134); catalogued as COSV100073771, COSV100075353, COSV60300125; called by mutect2, varscan2
- MUC5B | c.304G>A p.V102M | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1049302560, COSV71595941; called by muse, mutect2, varscan2
- MYOF | c.3669A>T p.K1223N | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.932); catalogued as COSV63709424; called by muse, mutect2, varscan2
- NCAM1 | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as rs782530698, COSV57526009; called by muse, mutect2, varscan2
- NCAPG | c.1421T>A p.V474D | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV99266231; called by muse, mutect2, varscan2
- NEBL | c.1276G>T p.E426* | Nonsense Mutation (SNP) | VAF 18/91 reads (20%) | catalogued as COSV101009383; called by muse, mutect2, varscan2
- NEFM | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.307); catalogued as COSV99647612; called by muse, mutect2, varscan2
- NLRP12 | c.466C>T p.R156W | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145803984, COSV60749290, COSV60756422; called by muse, mutect2, varscan2
- NLRP5 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 48/273 reads (18%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV66767799; called by muse, mutect2, varscan2
- ODF2L | c.437A>T p.N146I | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.234); catalogued as COSV54018972; called by muse, mutect2, varscan2
- OPN4 | c.868A>G p.S290G | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV54120101; called by muse, varscan2
- OR2B2 | c.905A>T p.K302I | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV57580856; called by muse, mutect2
- OR4D6 | c.749A>T p.H250L | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.411); catalogued as COSV100271859; called by muse, mutect2
- ORAI2 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs752254400, COSV62690645; called by muse, mutect2, varscan2
- PBDC1 | c.578A>G p.K193R | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV64896273; called by muse, mutect2
- PBRM1 | c.1690G>T p.E564* | Nonsense Mutation (SNP) | VAF 25/69 reads (36%) | catalogued as COSV56298417, COSV56307815; called by muse, mutect2, varscan2
- PCDHB12 | c.2330A>G p.Q777R | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV53401535; called by muse, mutect2
- PEX1 | c.1295T>G p.I432R | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99952446; called by muse, mutect2, varscan2
- PI4KA | c.2230G>A p.G744R | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55424772; called by muse, mutect2, varscan2
- PLS3 | c.562C>A p.L188I | Missense Mutation (SNP) | VAF 32/313 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as COSV99172624; called by muse, mutect2
- PMS1 | c.1157C>A p.S386* | Nonsense Mutation (SNP) | VAF 32/152 reads (21%) | catalogued as COSV59720583; called by muse, mutect2, varscan2
- PNLDC1 | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs763629906, COSV51706803; called by mutect2, varscan2
- POU4F2 | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.015); catalogued as rs777950064, COSV55585326; called by mutect2, varscan2
- PTPN9 | c.1150C>T p.R384C | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as rs756811878, COSV60723804, COSV60726258; called by muse, mutect2, varscan2
- RIC1 | c.814G>A p.G272S | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.999); catalogued as COSV52613693, COSV52616049; called by muse, mutect2, varscan2
- RNF151 | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.382); catalogued as COSV100364550; called by mutect2, varscan2
- ROCK1 | c.3040G>A p.D1014N | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.208); catalogued as COSV101296642, COSV67695055; called by muse, mutect2
- RYR2 | c.13382A>C p.K4461T | Missense Mutation (SNP) | VAF 45/166 reads (27%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.808); catalogued as COSV100773179, COSV100773532; called by muse, mutect2
- SCEL | c.1122T>G p.I374M (on ENST00000349847 / NM_144777.3; = p.I354M on NM_003843.4) | Missense Mutation (SNP) | VAF 13/227 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.413); catalogued as COSV100583284; called by muse, mutect2
- SHOX | c.598G>A p.V200I | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.13); catalogued as rs371048081, COSV100479324; called by muse, mutect2
- SLC4A10 | c.1116C>A p.F372L (on ENST00000446997 / NM_001354461.2; = p.F342L on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55762649, COSV55802025; called by muse, mutect2, varscan2
- SLFN5 | c.1682A>G p.Y561C | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as COSV55483908; called by muse, mutect2, varscan2
- SMIM7 | c.68T>A p.L23Q | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781079606, COSV99495529; called by muse, mutect2
- SNAP91 | c.286T>C p.Y96H | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52135786; called by muse, mutect2, varscan2
- SNCAIP | c.140C>A p.S47Y | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.726); catalogued as COSV54422659; called by muse, mutect2, varscan2
- SPATA31A1 | c.3913C>A p.H1305N | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs963544135; called by muse, mutect2, varscan2
- SPTBN5 | c.3290G>A p.R1097H | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs761524784, COSV100311395; called by mutect2, varscan2
- SRGAP3 | c.1711C>T p.R571* | Nonsense Mutation (SNP) | VAF 11/32 reads (34%) | catalogued as COSV64540670; called by muse, mutect2, varscan2
- ST8SIA4 | c.81A>T p.R27S | Missense Mutation (SNP) | VAF 39/116 reads (34%) | PolyPhen possibly damaging (0.879); catalogued as COSV51517401; called by muse, mutect2, varscan2
- STK31 | c.118C>G p.H40D | Missense Mutation (SNP) | VAF 46/179 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63459831; called by muse, mutect2, varscan2
- SVEP1 | c.8902G>T p.G2968W | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52844670; called by muse, mutect2, varscan2
- SYNE1 | c.22824G>T p.Q7608H (on ENST00000367255 / NM_182961.4; = p.Q7537H on NM_033071.3) | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99581904; called by muse, mutect2, varscan2
- TAZ | c.254G>T p.R85L | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV99186364; called by muse, varscan2
- TBCD | c.603C>A p.D201E | Missense Mutation (SNP) | VAF 57/267 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as COSV62808678; called by muse, mutect2, varscan2
- TCEAL1 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV101010137; called by muse, mutect2, varscan2
- TECPR2 | c.1232G>C p.S411T | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.985); catalogued as COSV100850244; called by muse, mutect2, varscan2
- TLR5 | c.62T>G p.I21S | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.586); catalogued as COSV60561025; called by muse, mutect2, varscan2
- TM7SF2 | c.694C>T p.L232F | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.987); catalogued as COSV54209705; called by muse, mutect2, varscan2
- TOX2 | c.1310del p.P437Rfs*136 (on ENST00000358131 / NM_001098798.2; = p.P413Rfs*136 on NM_032883.3) | Frame Shift Del (DEL) | VAF 6/64 reads (9%) | catalogued as COSV57886485; called by mutect2, varscan2
- TSHR | c.1144G>T p.D382Y | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.956); catalogued as COSV53315861, COSV53333094; called by muse, mutect2, varscan2
- TSPAN7 | c.512C>T p.P171L | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54534723; called by muse, mutect2, varscan2
- TTN | c.39112C>T p.R13038* (on ENST00000591111; = p.R5614* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 13/44 reads (30%) | catalogued as rs776970935, COSV60365265; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.1915C>A p.Q639K (on ENST00000591111; = p.Q593K on NM_003319.4) | Missense Mutation (SNP) | VAF 22/188 reads (12%) | PolyPhen benign (0.121); catalogued as COSV60382144; called by muse, mutect2, varscan2
- UFL1 | c.1028A>C p.Q343P | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV100990152; called by muse, mutect2, varscan2
- WDR7 | c.1136T>C p.L379S | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99590597; called by muse, mutect2, varscan2
- ZNF304 | c.36T>A p.S12R | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV99988906; called by muse, mutect2, varscan2
- ZNF486 | c.773A>C p.K258T | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.348); catalogued as COSV58723192; called by muse, mutect2, varscan2
- ZNF639 | c.1243A>G p.M415V | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.678); catalogued as COSV58384824; called by muse, mutect2, varscan2
- ZPBP | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.916); catalogued as rs778999986, COSV50427017; called by muse, mutect2, varscan2
- ABCA9 | c.3046A>G p.M1016V | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2
- CYFIP1 | c.1460T>G p.F487C | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- DXO | c.114del p.P41Lfs*88 | Frame Shift Del (DEL) | VAF 7/27 reads (26%) | called by mutect2, pindel, varscan2
- H3-5 | c.93del p.S32Lfs*5 | Frame Shift Del (DEL) | VAF 7/51 reads (14%) | called by mutect2, pindel, varscan2
- LRRC47 | c.1635dup p.S546Lfs*61 | Frame Shift Ins (INS) | VAF 8/25 reads (32%) | called by mutect2, pindel, varscan2
- OR6T1 | c.588del p.K196Nfs*18 | Frame Shift Del (DEL) | VAF 12/47 reads (26%) | called by mutect2, pindel, varscan2
- PREX2 | c.1909_1912delinsATA p.F637Ifs*7 | Frame Shift Del (DEL) | VAF 41/163 reads (25%) | called by pindel, varscan2*
- ADCY6 | c.660G>A p.A220= | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as rs1228329436, COSV57170940; called by muse, mutect2, varscan2
- AGRN | c.2283G>A p.V761= | Silent (SNP) | VAF 19/89 reads (21%) | catalogued as COSV65072643; called by muse, mutect2, varscan2
- BRD8 | c.2979C>A p.L993= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as COSV54732738; called by muse, mutect2, varscan2
- C3orf70 | c.450G>A p.P150= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as rs61747891; called by muse, mutect2, varscan2
- CCAR1 | c.2163T>C p.Y721= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as rs752569768, COSV99771477; called by muse, mutect2, varscan2
- CCT7 | c.1631G>A p.*544= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as rs756429492, COSV54586399; called by muse, mutect2, varscan2
- CDC42BPA | c.1722G>A p.L574= | Silent (SNP) | VAF 39/158 reads (25%) | catalogued as COSV62023272; called by muse, mutect2, varscan2
- DNAH9 | c.7236T>C p.P2412= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV99308521; called by mutect2, varscan2
- ERICH3 | c.2397A>C p.G799= | Silent (SNP) | VAF 25/101 reads (25%) | catalogued as COSV100446002; called by muse, mutect2
- FOXP3 | c.873C>T p.V291= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs782371089, COSV100873275; called by muse, mutect2
- GPR62 | c.45G>A p.S15= | Silent (SNP) | VAF 31/52 reads (60%) | catalogued as COSV59056402; called by muse, mutect2, varscan2
- GSDME | c.1428C>A p.V476= | Silent (SNP) | VAF 7/103 reads (7%) | called by muse, mutect2
- HHIPL2 | c.1839A>G p.P613= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as COSV58568246; called by muse, mutect2, varscan2
- HIPK3 | c.3333C>T p.H1111= | Silent (SNP) | VAF 58/159 reads (36%) | catalogued as COSV57566237; called by muse, mutect2, varscan2
- IBTK | c.3546T>G p.P1182= | Silent (SNP) | VAF 15/97 reads (15%) | catalogued as COSV100091596; called by muse, mutect2, varscan2
- IGLON5 | c.243C>T p.S81= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as rs775852241, COSV54534950; called by muse, mutect2, varscan2
- KIF11 | c.282T>A p.I94= | Silent (SNP) | VAF 39/154 reads (25%) | catalogued as COSV99586214; called by muse, mutect2, varscan2
- KRTAP1-5 | c.147C>T p.S49= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV100721416; called by muse, mutect2, varscan2
- MAP3K5 | c.3171C>T p.I1057= | Silent (SNP) | VAF 11/103 reads (11%) | catalogued as rs368851337, COSV62892463; called by muse, mutect2, varscan2
- MRGPRX3 | c.210G>A p.A70= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as rs749919475, COSV66934205; called by muse, mutect2, varscan2
- MYF5 | c.273C>T p.R91= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV57355011; called by muse, mutect2, varscan2
- NLRP4 | c.669G>A p.P223= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as rs746075034, COSV56707602, COSV56708334; called by muse, mutect2, varscan2
- OBSCN | c.14961G>A p.V4987= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV99485114; called by muse, mutect2, varscan2
- PDZRN3 | c.2019C>T p.A673= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs377349000; called by muse, mutect2, varscan2
- POLH | c.1674C>A p.S558= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV64781173; called by muse, mutect2, varscan2
- SASH3 | c.1077C>T p.R359= | Silent (SNP) | VAF 11/97 reads (11%) | catalogued as rs373319291, COSV63556765; called by muse, mutect2, varscan2
- SERPING1 | c.721C>A p.R241= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV99558206; called by mutect2, varscan2
- SHANK1 | c.3522C>A p.G1174= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as COSV53255351; called by muse, varscan2
- STIL | c.1623T>A p.V541= | Silent (SNP) | VAF 12/107 reads (11%) | catalogued as COSV54554226; called by muse, mutect2, varscan2
- TGFB1 | c.396T>C p.Y132= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs199696548, COSV99700313; called by mutect2, varscan2
- THBD | c.1434C>T p.T478= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV65703265; called by muse, mutect2, varscan2
- TRABD | c.1035C>T p.S345= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as rs1018464670; called by muse, mutect2
- TRIM37 | c.174C>G p.L58= | Silent (SNP) | VAF 15/122 reads (12%) | catalogued as rs1425339181, COSV51887303; called by muse, mutect2, varscan2
- TRPS1 | c.2586G>A p.K862= (on ENST00000220888 / NM_001330599.2; = p.K875= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs773091182, COSV55264519; called by muse, mutect2, varscan2
- UGT2B4 | c.534C>T p.Y178= | Silent (SNP) | VAF 35/78 reads (45%) | catalogued as rs370531105; called by muse, mutect2, varscan2
- VMP1 | c.81C>A p.P27= | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as COSV51873014; called by muse, mutect2, varscan2
- ZBBX | c.1129T>C p.L377= | Silent (SNP) | VAF 71/163 reads (44%) | catalogued as COSV100285078; called by muse, mutect2, varscan2
- ZIC4 | c.714C>T p.F238= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV101267844, COSV67170598; called by muse, mutect2, varscan2
- HOXB4 | chr17:48579902 T>C | 5'Flank (SNP) | VAF 49/161 reads (30%) | catalogued as COSV100203870; called by muse, mutect2, varscan2
- OBSCN | c.11660-1192C>T | Intron (SNP) | VAF 20/69 reads (29%) | catalogued as rs550560195, COSV52834472; called by muse, mutect2, varscan2
- TTN | c.34265-5062G>A | Intron (SNP) | VAF 8/73 reads (11%) | catalogued as COSV60382137; called by mutect2, varscan2
